Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A1CI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A1CI-01A (Primary Tumor).

[page 1 of 3]
Adenocarcinoma, endometrioid, Nos 8380/3
Site Code: Endometrium 254.1

1/9/11

hr

MR #:
Name:
Birthdate:

Accession No:
Report to Dr:

Location:

Accn. Date:
Coll. Date:

DIAGNOSIS:

- A. CLINICALLY UTERUS, CERVIX, TUBES AND OVARIES:
1. EXTENSIVE SUPERFICIALLY INVASIVE WELL DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE I, WITH MINIMAL MYOMETRIAL INVASION AND NO LYMPHOVASCULAR INVASION, LOWER UTERINE SEGMENT NEGATIVE, EXCISED.
2. MAXIMUM TUMOR DIMENSION, 12 CM.
3. OVARIES AND TUBES CONSISTENT WITH AGE.
4. MILD CHRONIC CERVICITIS.
B. CLINICALLY LEFT PELVIC LYMPH NODES: FIVE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/5).
C. CLINICALLY LEFT PERIAORTIC LYMPH NODES: TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).
D. CLINICALLY RIGHT PELVIC LYMPH NODES: EIGHT REGIONAL LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/8).
E. CLINICALLY RIGHT PARA-AORTIC LYMPH NODES: THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

TISSUE:

- A. Uterus, cervix, tubes, ovaries (F.S with (undecipherable)
B. Left pelvic lymph node
C. Left periaortic lymph node
D. Right pelvic lymph node
E. Pariaortic lymph node

PRE-OP DX:

Adenocarcinoma of uterus

POST-OP DX:

Same as pre-op

HISTORY:

FROZEN SECTION:

- A. Endometrial carcinoma superficially invasive as per

GROSS:

The specimen is received fresh in five parts.

Part A consists of an intact uterus and cervix with bilaterally attached adnexa weighing 470 grams. The uterus measures 13 X 10 X 10 cm. The right fallopian tube appears previously ligated and measures 2.5 X 1 X 1 cm. The attached ovary measures 2 X 1 X 1 cm. On sectioning is has a solid pink tan parenchyma which is not grossly remarkable. The left fallopian tube is previously ligated and measures 2.5 X 0.5 X 0.5 cm. The attached ovary

(continued on next page)

[page 2 of 3]
MR #:
Name:
Birthdate:

Accession No:
Report to Dr:

Location:

Accn. Date:
Coll. Date:

DIAGNOSIS:

- A. CLINICALLY UTERUS, CERVIX, TUBES AND OVARIES:
1. EXTENSIVE SUPERFICIALLY INVASIVE WELL DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE I, WITH MINIMAL MYOMETRIAL INVASION AND NO LYMPHOVASCULAR INVASION, LOWER UTERINE SEGMENT NEGATIVE, EXCISED.
2. MAXIMUM TUMOR DIMENSION, 12 CM.
3. OVARIES AND TUBES CONSISTENT WITH AGE.
4. MILD CHRONIC CERVICITIS.
B. CLINICALLY LEFT PELVIC LYMPH NODES: FIVE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/5).
C. CLINICALLY LEFT PERIAORTIC LYMPH NODES: TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).
D. CLINICALLY RIGHT PELVIC LYMPH NODES: EIGHT REGIONAL LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/8).
E. CLINICALLY RIGHT PARA-AORTIC LYMPH NODES: THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

TISSUE:

- A. Uterus, cervix, tubes, ovaries (F.S with (undecipherable)
B. Left pelvic lymph node
C. Left periaortic lymph node
D. Right pelvic lymph node
E. Pariaortic lymph node

PRE-OP DX:

Adenocarcinoma of uterus

POST-OP DX:

Same as pre-op

HISTORY:

FROZEN SECTION:

- A. Endometrial carcinoma superficially invasive as per

GROSS:

The specimen is received fresh in five parts.

Part A consists of an intact uterus and cervix with bilaterally attached adnexa weighing 470 grams. The uterus measures 13 X 10 X 10 cm. The right fallopian tube appears previously ligated and measures 2.5 X 1 X 1 cm. The attached ovary measures 2 X 1 X 1 cm. On sectioning is has a solid pink tan parenchyma which is not grossly remarkable. The left fallopian tube is previously ligated and measures 2.5 X 0.5 X 0.5 cm. The attached ovary

(continued on next page)

[page 3 of 3]
IHPAA Discrepancy		

(continued)

PAGE

MR #:
Name:
Birthdate:

Accession No:
Report to Dr:

Surgical Pathology Cancer Case Summary (Checklist)
Based on AJCC/UICC TNM, 6th edition, Applies to invasive carcinomas only

Organ:

MACROSCOPIC

SPECIMEN TYPE:

Hysterectomy

TUMOR SITE

Specify location:

TUMOR SIZE

Greatest dimension: 12 cm

OTHER ORGANS PRESENT

Bilateral ovaries, fallopian tubes

MICROSCOPIC

HISTOLOGIC TYPE:

Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE:

G1: 5+ or less nonsquamous solid growth

MYOMETRIAL INVASION

Invasion present

Specify depth of invasion: 2.2 mm

Specify myometrial thickness: 14.3 mm

EXTENT OF INVASION TNM

pT1b: Tumor invades less than one-half

REGIONAL LYMPH NODES (pN)

pN0: No regional lymph node metastasis

Specify Number examined: 16 ; Number involved: 0

DISTANT METASTASIS (pM)

pMx: Cannot be assessed

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L)

Absent

MR #:

(continued on next page)

Accession No:

Source: NCI Genomic Data Commons file 2cb2ce7e-e8de-4a67-9442-050b63b95604 (TCGA-AX-A1CI.7F264403-0A76-4FAD-9A57-7C555F69375C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).